Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5531, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5531-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 5.9. The patient also has a history of biopsy on [REDACTED]; this biopsy reveals: Poorly differentiated prostatic adenocarcinoma, Gleason score 4+4 = 8 in the left mid of the prostate. The patient also has a history of [REDACTED]
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

TCGA - EJ - 5531**ADDENDA:****Addendum**

The combination immunohistochemical stain PIN4 (p63, CK903, P504S) was performed on slide 3FF. The stain highlights neoplastic glands located in the periprostatic adipose tissue. These glands lack basal cells, and the cytoplasm is highlighted by racemase.

This result supports extracapsular extension, noted in the previously rendered report.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN FOURTEEN LYMPH NODES (0/14).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN TWENTY-ONE LYMPH NODES (0/21).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -
A. PROSTATE ADENOCARCINOMA, BOTH ACINAR AND DUCTAL TYPE, GLEASON SCORE 4 + 3 = 7.

- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.9 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS EVIDENCE OF MULTIFOCAL EXTRACAPSULAR EXTENSION IN THE LEFT ANTERIOR AND POSTERIOR MID REGION OF THE PROSTATE (SLIDES 3U, 3FF, 3GG), APPROXIMATELY 0.5 CM IN COMBINED TOTAL DIMENSION. THE CARCINOMA IS ORGAN-CONFINED IN ALL OTHER REGIONS OF THE PROSTATE.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- K. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 5.9
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	67.53gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	35
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file d071bff1-1096-4a54-9bae-5ee9d2796336 (TCGA-EJ-5531.0F235AAD-3F99-4AC4-919E-0A4290C02075.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).